Somatic mutation profile of tumor specimen ER-AC0F-TTP1-A (aliquot ER-AC0F-TTP1-A-1-0-D-A475-34) from EXCEPTIONAL_RESPONDERS case ER-AC0F, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 58.2 years (21,260 days).
Specimen ER-AC0F-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d16b129-cb49-4f4f-9b75-8b52207caebc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-AC0F-NT1-A (Solid Tissue Normal), aliquot ER-AC0F-NT1-A-2-0-D-A598-34; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1770660-1c6c-4b48-92a9-4a1c85566794

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRF1 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1454671489; called by muse, mutect2, varscan2
- PLEC | c.7079G>A p.R2360H (on ENST00000322810 / NM_201380.4; = p.R2250H on NM_000445.5) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.379); catalogued as rs565225660, COSV59653509; ClinVar: uncertain significance; called by muse, varscan2
- TMEM63B | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as rs771732590, COSV52478552; called by mutect2, varscan2
- CIPC | c.249G>C p.K83N | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- COL16A1 | c.1661A>G p.E554G | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, mutect2
- DHX40 | c.134A>G p.Q45R | Missense Mutation (SNP) | VAF 22/393 reads (6%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.775); called by muse, mutect2
- PLXDC1 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2
- CDR1 | c.612G>A p.K204= | Silent (SNP) | VAF 12/360 reads (3%) | catalogued as COSV100983406; called by muse, mutect2
- TBC1D4 | c.795C>T p.D265= | Silent (SNP) | VAF 3/18 reads (17%) | called by muse, varscan2
